Somatic mutation profile of tumor specimen 0DMBM6 from CCDI case PBBXMP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.5 years (5,310 days).
Specimen 0DMBM6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1479844-7250-4d16-9ca9-e258b75fcd08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec5cc2b4-4396-4be1-91e0-957c3604c810

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBFOX3 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1226535060; called by muse, mutect2, varscan2
- BIRC5 | c.408G>A p.E136= | Silent (SNP) | VAF 34/866 reads (4%) | called by muse, mutect2
